Somatic mutation profile of tumor specimen TARGET-20-PANLRE-09A (aliquot TARGET-20-PANLRE-09A-01D) from TARGET case TARGET-20-PANLRE, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.4 years (3,417 days).
Specimen TARGET-20-PANLRE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4357184c-0124-40e9-8f1b-0339f6dfc13e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANLRE-14A (Bone Marrow Normal), aliquot TARGET-20-PANLRE-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a779c251-d678-4646-bf49-1660d53745f7

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 76/396 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ARPIN | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375602115; called by muse, mutect2, varscan2
- BOC | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767756953, COSV56352222; called by muse, mutect2, varscan2
- DHX15 | c.664C>G p.R222G | Missense Mutation (SNP) | VAF 114/351 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61028061, COSV61028114, COSV61028271; called by muse, mutect2, varscan2
- LRIG3 | c.2143G>A p.V715I | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs374158553; called by muse, mutect2, varscan2
- PCBP1 | c.82A>T p.I28F | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- RELN | c.833C>A p.S278* | Nonsense Mutation (SNP) | VAF 23/426 reads (5%) | called by muse, mutect2
- DDB2 | c.642A>G p.R214= | Silent (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
